Gene-level copy-number profile of tumor specimen HTMCP-01-15-00370-01A from CGCI case HTMCP-01-15-00370, project CGCI-HTMCP-DLBCL (HIV+ Tumor Molecular Characterization Project - Diffuse Large B-Cell Lymphoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Diffuse large B-cell lymphoma, NOS; Tissue or organ of origin: Hematopoietic system, NOS; Age at diagnosis: 45.6 years (16,648 days).
Specimen HTMCP-01-15-00370-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 1f348520-9fde-4f1d-b7be-16df935e353c.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HTMCP-01-15-00370-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,733 have no estimate.
https://portal.gdc.cancer.gov/files/5e685e66-a3e8-4b72-8893-dc02ca676de1

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 59; copy number 1: 4,637; copy number 2: 49,919; copy number 3: 3,413; copy number 4: 712; copy number 5: 36; copy number 6: 108; copy number 8: 6.

Homozygous deletions (total copy number 0; autosomes only): 59 genes in 8 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:61,659,733–61,662,690, 1 gene: AL935212.1.
- chr9:64,621,560–64,765,535, 5 genes: AQP7P2, AL445665.1, BMS1P11, AL359955.2, IGKV1OR-2.
- chr9:65,189,995–65,230,861, 3 genes: BMS1P12, AL512605.1, AL512605.2.
- chr9:138,199,933–138,253,217, 2 genes: AL954642.1, FAM157B.
- chr14:106,037,902–106,324,760, 38 genes (within-gene range 0–2): IGHV2-5, IGHVIII-5-1, IGHVIII-5-2, IGHV3-6, IGHV3-7, IGHV3-64D, IGHV5-10-1, IGHV3-11, IGHVIII-11-1, IGHV1-12, IGHV3-13, IGHVIII-13-1, IGHV1-14, IGHV3-15, IGHVII-15-1, IGHV3-16, IGHVIII-16-1, IGHV1-17, SLC20A1P2, IGHV1-18, IGHV3-19, AC247036.1, IGHV3-20, IGHV3-21, IGHV3-22, IGHVII-22-1, IGHVIII-22-2, IGHV3-23, IGHV1-24, HOMER2P2, LINC00226, IGHV3-25, IGHVIII-25-1, IGHV2-26, IGHVIII-26-1, IGHVII-26-2, IGHV7-27, IGHV4-28.
- chr14:106,335,082–106,335,613, 1 gene (within-gene range 0–2): IGHV3-30.
- chr14:106,349,283–106,349,792, 1 gene (within-gene range 0–2): IGHV4-31.
- chr14:106,359,793–106,397,114, 8 genes (within-gene range 0–2): IGHV3-33, IGHVII-33-1, IGHV3-33-2, IGHV4-34, IGHV7-34-1, IGHV3-35, IGHV3-36, IGHV3-37.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 150 genes in 10 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:200,973,718–201,071,671, 1 gene, copy number 5 (within-gene range 4–5): FAM126B.
- chr2:230,587,121–230,587,227, 1 gene, copy number 5: RNU6-451P.
- chr2:231,706,895–231,812,352, 9 genes, copy number 5: PTMA, U4, MIR1244-1, PDE6D, AC073476.3, COPS7B, RPL28P2, AC073476.2, AC073476.1.
- chr3:195,274,745–198,123,232, 112 genes, copy number 6–8 (broad region; genes not listed).
- chr7:102,285,091–102,339,115, 5 genes, copy number 5: SH2B2, MIR4285, AC091390.1, Y_RNA, PMS2P12.
- chr9:64,810,865–64,811,429, 1 gene, copy number 6: BNIP3P4.
- chr9:65,287,914–65,323,015, 1 gene, copy number 5: CBWD4P.
- chr17:38,925,168–38,996,624, 3 genes, copy number 5–6: LINC00672, FBXO47, AC006441.2.
- chr17:42,313,324–42,440,259, 3 genes, copy number 5: STAT3, CAVIN1, RNU7-97P.
- chr17:43,216,941–43,305,397, 14 genes, copy number 5 (within-gene range 4–5): CCDC200, RNU2-1, U2, U2, U2, U2, U2, U2, U2, U2, U2, U2, U2, U2.

Autosomal genes at a single copy (total copy number 1): 1,781. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
